Somatic mutation profile of tumor specimen BA2459D (aliquot aq-BA2459D) from BEATAML1.0 case 2350, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Primary diagnosis: Acute myeloid leukemia without maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 55.5 years (20,282 days).
Specimen BA2459D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f6e2f2d0-4038-4335-bf64-adcffa4fbc2b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2207D (Solid Tissue Normal), aliquot aq-BA2207D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b85c413f-d647-4b2b-833d-8861b25f4ca2

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA7 | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs769748741, COSV54027457; called by muse, varscan2
- DNAH9 | c.9017C>A p.T3006K | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as COSV52343181; called by muse, mutect2
- CGN | c.642C>A p.S214R | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KDM4C | c.1951C>A p.L651I | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.164); called by muse, mutect2
- MOCOS | c.1634C>T p.S545L | Missense Mutation (SNP) | VAF 67/168 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC5A5 | c.106C>A p.L36M | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.104); called by muse, mutect2
- UGT1A9 | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, varscan2
- VPS13C | c.3594G>T p.M1198I (on ENST00000644861 / NM_020821.3; = p.M1155I on NM_017684.5) | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.006); called by muse, mutect2
- ADIPOR1 | c.435C>T p.F145= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as rs756017133, COSV61850784; called by muse, mutect2, varscan2
- PRKCA | c.1194G>A p.P398= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as rs761333063, COSV52582472; called by muse, varscan2
- LINC02693 | n.699G>T | RNA (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
